Somatic mutation profile of tumor specimen ALCH-B2V8-TTP1-A (aliquot ALCH-B2V8-TTP1-A-1-0-D-A77P-36) from ALCHEMIST case ALCH-B2V8, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 44.7 years (16,314 days).
Specimen ALCH-B2V8-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 008c79b9-717e-41f7-8bbc-006a491a8398.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2V8-NB1-A (Blood Derived Normal), aliquot ALCH-B2V8-NB1-A-1-0-D-A77P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b335426-544f-4a8b-8965-390d777f5582

The open-access MAF lists 452 somatic variants for this specimen: 317 protein-altering or splice-affecting, 82 silent, 53 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 266, Silent 82, Nonsense Mutation 23, Intron 21, RNA 15, Frame Shift Del 9, Splice Site 7, 5'Flank 7, Splice Region 6, Frame Shift Ins 5, 3'UTR 5, 5'UTR 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 188/491 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- MGAT2 | c.869C>T p.S290F | Missense Mutation (SNP) | VAF 99/302 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs104894446, CM960961; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 99/157 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCD2 | c.856G>T p.A286S | Missense Mutation (SNP) | VAF 28/271 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as rs755818457, COSV58049475; called by muse, mutect2, varscan2
- ADGRL3 | c.4657G>T p.D1553Y (on ENST00000506720 / NM_001322402.2; = p.D1442Y on NM_015236.6) | Missense Mutation (SNP) | VAF 84/188 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV72231686; called by muse, mutect2, varscan2
- ARHGAP28 | c.714G>T p.R238S (on ENST00000383472 / NM_001366230.1; = p.R79S on NM_001010000.3) | Missense Mutation (SNP) | VAF 62/203 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV51640428; called by muse, mutect2, varscan2
- ARSI | c.752G>T p.R251L | Missense Mutation (SNP) | VAF 69/191 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV100155986; called by muse, mutect2, varscan2
- ARSI | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 69/191 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as rs781658106, COSV60816605; called by muse, mutect2, varscan2
- ASB3 | c.21C>G p.Y7* | Nonsense Mutation (SNP) | VAF 38/382 reads (10%) | catalogued as COSV54857928, COSV54858005; called by muse, mutect2
- ASB5 | c.671G>T p.G224V | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749505830; called by muse, mutect2, varscan2
- B4GAT1 | c.878C>A p.T293N | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.158); catalogued as rs769243318; called by muse, mutect2
- BEND4 | c.664C>A p.H222N | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as COSV101549692; called by muse, mutect2, varscan2
- BRCA2 | c.7312G>T p.D2438Y | Missense Mutation (SNP) | VAF 82/286 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs776936973; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C4orf54 | c.395G>T p.C132F | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.922); catalogued as rs1319159616; called by muse, mutect2, varscan2
- CABP2 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.242); catalogued as rs767124487; called by muse, mutect2, varscan2
- CACNG6 | c.65G>T p.R22L | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as rs534917640; called by muse, mutect2, varscan2
- CCKBR | c.785G>C p.R262T | Missense Mutation (SNP) | VAF 26/386 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs1315793560; called by muse, mutect2
- CFAP46 | c.1566C>A p.D522E | Missense Mutation (SNP) | VAF 138/248 reads (56%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.837); catalogued as rs1455077230; called by muse, mutect2, varscan2
- CFL1 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 18/364 reads (5%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs11550158, COSV100354237; called by muse, mutect2
- CGREF1 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 111/652 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as COSV53149588; called by muse, mutect2, varscan2
- CLCNKB | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs746767761, COSV65161302; called by muse, mutect2
- COL25A1 | c.643G>T p.D215Y | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as rs1205668803, COSV67646944; called by muse, mutect2, varscan2
- CPXM2 | c.653+1G>T p.X218_splice | Splice Site (SNP) | VAF 98/163 reads (60%) | catalogued as COSV99583604; called by muse, mutect2, varscan2
- CR1 | c.5332C>A p.P1778T | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65457562; called by muse, mutect2, varscan2
- CSMD1 | c.9469G>T p.G3157* (on ENST00000520002; = p.G3156* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 58/127 reads (46%) | catalogued as COSV100145286; called by muse, mutect2, varscan2
- CSMD3 | c.5470C>T p.Q1824* (on ENST00000297405 / NM_001363185.1; = p.Q1720* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 286/625 reads (46%) | catalogued as COSV52294049, COSV52350570; called by muse, mutect2, varscan2
- CTNND1 | c.2635T>C p.S879P (on ENST00000399050 / NM_001085458.2; = p.S873P on NM_001331.3) | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs750790386; called by muse, mutect2, varscan2
- DIP2B | c.1294A>G p.I432V | Missense Mutation (SNP) | VAF 110/312 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.173); catalogued as rs780738932; called by muse, mutect2, varscan2
- DLGAP2 | c.929G>T p.R310L | Missense Mutation (SNP) | VAF 105/359 reads (29%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.993); catalogued as COSV70101903, COSV70104658; called by muse, mutect2, varscan2
- ERICH3 | c.770G>T p.R257I | Missense Mutation (SNP) | VAF 37/177 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV58602702; called by muse, mutect2, varscan2
- ERN2 | c.1501G>C p.A501P | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1334574872; called by muse, mutect2, varscan2
- ESPL1 | c.4419G>T p.R1473S | Missense Mutation (SNP) | VAF 132/281 reads (47%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs1159757302, COSV57764719; called by muse, mutect2, varscan2
- F9 | c.427C>A p.Q143K | Missense Mutation (SNP) | VAF 104/140 reads (74%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); catalogued as CM005428, CM057684, CM940500; called by muse, mutect2, varscan2
- FBN3 | c.1046G>T p.R349L | Missense Mutation (SNP) | VAF 99/147 reads (67%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV99561180, COSV99561297; called by muse, mutect2, varscan2
- FBXO46 | c.1534G>A p.V512M | Missense Mutation (SNP) | VAF 11/202 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58348024; called by muse, mutect2
- FOXD4L1 | c.994G>T p.G332W | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52074607; called by mutect2, varscan2
- FRZB | c.374A>T p.K125M | Missense Mutation (SNP) | VAF 80/279 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.033); catalogued as COSV99717626; called by muse, mutect2, varscan2
- GAST | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 59/179 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.851); catalogued as COSV61475817; called by muse, mutect2, varscan2
- GREB1L | c.392C>A p.S131* | Nonsense Mutation (SNP) | VAF 128/384 reads (33%) | catalogued as COSV52555447; called by muse, mutect2, varscan2
- H2BC4 | c.108G>C p.E36D | Missense Mutation (SNP) | VAF 16/272 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.047); catalogued as COSV100019720; called by muse, mutect2
- IGFBP1 | c.397G>T p.E133* | Nonsense Mutation (SNP) | VAF 39/184 reads (21%) | catalogued as COSV51874719; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1577C>A p.A526D | Missense Mutation (SNP) | VAF 57/247 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV100149635; called by muse, mutect2, varscan2
- ISCA2 | c.268A>G p.T90A | Missense Mutation (SNP) | VAF 86/281 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as rs1566607048; called by muse, mutect2, varscan2
- KAT8 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.039); catalogued as rs759640339; called by muse, mutect2, varscan2
- KCTD12 | c.613C>T p.R205W | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as rs746569069; called by muse, mutect2, varscan2
- KRT73 | c.819G>C p.G273= | Splice Region (SNP) | VAF 46/141 reads (33%) | catalogued as COSV59838372; called by muse, mutect2, varscan2
- LAMA2 | c.5893G>A p.E1965K | Missense Mutation (SNP) | VAF 70/252 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.166); catalogued as rs886061052; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMB4 | c.2231C>T p.P744L | Missense Mutation (SNP) | VAF 46/234 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as COSV52721350; called by muse, mutect2, varscan2
- LATS2 | c.1055G>A p.R352Q | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as rs1211577619, COSV66873484; called by muse, mutect2, varscan2
- LIPC | c.575-2A>G p.X192_splice | Splice Site (SNP) | VAF 10/174 reads (6%) | catalogued as rs1328254005; called by muse, mutect2
- LRP1B | c.13481C>A p.S4494Y | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1226755936; called by muse, varscan2
- LRRC53 | c.1141G>T p.E381* | Nonsense Mutation (SNP) | VAF 24/89 reads (27%) | catalogued as rs1271863770, COSV53945976; called by muse, mutect2, varscan2
- LRRTM4 | c.846G>T p.L282F | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69139392, COSV69140820; called by muse, mutect2, varscan2
- MAG | c.842G>T p.R281L | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.089); catalogued as rs778233016; called by muse, mutect2, varscan2
- MARVELD2 | c.1571A>G p.E524G | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756327348, COSV57780447; called by muse, mutect2
- MSL3 | c.1115G>A p.R372H (on ENST00000312196 / NM_078629.4; = p.R206H on NM_006800.4) | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs1231114955; called by muse, mutect2, varscan2
- NOL4 | c.938C>A p.A313E | Missense Mutation (SNP) | VAF 143/462 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.196); catalogued as COSV99304843; called by mutect2, varscan2
- NOTCH3 | c.2180C>T p.P727L | Missense Mutation (SNP) | VAF 42/191 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.166); catalogued as COSV54629314; called by muse, mutect2, varscan2
- NOX5 | c.1472C>T p.P491L | Missense Mutation (SNP) | VAF 64/209 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1017822533; called by muse, mutect2, varscan2
- NPFFR2 | c.1000C>T p.L334F | Missense Mutation (SNP) | VAF 115/291 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV100440471; called by muse, mutect2, varscan2
- OGDHL | c.28C>G p.R10G | Missense Mutation (SNP) | VAF 182/319 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as COSV65100794; called by muse, mutect2, varscan2
- OR2T8 | c.721T>A p.S241T | Missense Mutation (SNP) | VAF 62/289 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60664219; called by muse, mutect2, varscan2
- OR4C6 | c.859C>A p.L287M | Missense Mutation (SNP) | VAF 64/250 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.944); catalogued as rs1429288691; called by muse, mutect2, varscan2
- OR4N2 | c.811del p.V271Ffs*7 | Frame Shift Del (DEL) | VAF 120/709 reads (17%) | catalogued as COSV60054228; called by mutect2, pindel, varscan2
- OR52B6 | c.965G>T p.G322V | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.067); catalogued as COSV100798463; called by muse, mutect2
- OR52K1 | c.479C>A p.P160Q | Missense Mutation (SNP) | VAF 19/458 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100297609, COSV56904531; called by muse, mutect2
- OR56B4 | c.923A>C p.Q308P | Missense Mutation (SNP) | VAF 32/211 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.13); catalogued as COSV57205198; called by muse, mutect2
- OR5AN1 | c.355A>G p.M119V | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs757929099; called by muse, mutect2, varscan2
- OR5L2 | c.529T>A p.F177I | Missense Mutation (SNP) | VAF 14/201 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV65724896; called by muse, mutect2
- OTOP2 | c.821G>T p.G274V | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.159); catalogued as COSV58883432; called by muse, mutect2, varscan2
- PCDHB7 | c.2164C>A p.R722S | Missense Mutation (SNP) | VAF 114/1240 reads (9%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.106); catalogued as COSV50753646; called by muse, mutect2
- PCDHGA8 | c.1936G>A p.V646I | Missense Mutation (SNP) | VAF 11/286 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.477); catalogued as COSV53949255; called by muse, mutect2
- PCLO | c.5850G>T p.M1950I | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as COSV61639787; called by muse, mutect2, varscan2
- PCLO | c.5849T>A p.M1950K | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV61653027; called by muse, mutect2, varscan2
- PHYHIP | c.27C>A p.S9R | Missense Mutation (SNP) | VAF 63/274 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.23); catalogued as COSV58688709; called by muse, mutect2, varscan2
- PLEC | c.2990C>T p.P997L (on ENST00000322810 / NM_201380.4; = p.P887L on NM_000445.5) | Missense Mutation (SNP) | VAF 12/236 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs1270898395; called by muse, mutect2
- POT1 | c.1337C>T p.P446L | Missense Mutation (SNP) | VAF 111/252 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.361); catalogued as rs761176134; called by muse, mutect2, varscan2
- POTEC | c.1399G>C p.E467Q | Missense Mutation (SNP) | VAF 15/161 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1210507056, COSV100743654; called by muse, mutect2, varscan2
- PRUNE2 | c.7516G>T p.A2506S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as rs1489658924; called by muse, mutect2
- PSG5 | c.965-8C>A | Splice Region (SNP) | VAF 45/223 reads (20%) | catalogued as rs1474394966; called by muse, mutect2, varscan2
- PTGFR | c.626G>T p.G209V | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66116001; called by muse, mutect2, varscan2
- RETREG2 | c.1444G>T p.E482* | Nonsense Mutation (SNP) | VAF 47/164 reads (29%) | catalogued as COSV56088108; called by muse, mutect2, varscan2
- RNMT | c.935G>T p.G312V | Missense Mutation (SNP) | VAF 67/175 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51084276, COSV51091802; called by muse, mutect2, varscan2
- RP1L1 | c.2500G>T p.A834S | Missense Mutation (SNP) | VAF 91/174 reads (52%) | SIFT tolerated (0.49); PolyPhen benign (0.021); catalogued as COSV66752069; called by muse, mutect2, varscan2
- RTL1 | c.300G>T p.E100D | Missense Mutation (SNP) | VAF 61/211 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.834); catalogued as COSV101128232; called by muse, mutect2, varscan2
- SALL1 | c.1760C>A p.P587H | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV51760843, COSV51762375; called by muse, mutect2, varscan2
- SCN1A | c.197G>T p.G66V | Missense Mutation (SNP) | VAF 89/284 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57685284; called by muse, mutect2, varscan2
- SEMA4F | c.1482+1G>A p.X494_splice | Splice Site (SNP) | VAF 145/313 reads (46%) | catalogued as rs566725824, COSV100336154, COSV60284396; called by muse, mutect2, varscan2
- SIDT1 | c.1209C>A p.S403R | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV53502189; called by muse, mutect2, varscan2
- SLC12A6 | c.1636G>C p.V546L (on ENST00000354181 / NM_001365088.1; = p.V495L on NM_005135.2) | Missense Mutation (SNP) | VAF 57/345 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as rs1335237469, COSV99273447; called by muse, mutect2, varscan2
- SLC9A2 | c.1385C>T p.T462M | Missense Mutation (SNP) | VAF 121/325 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs772980419, COSV52135881; called by muse, mutect2, varscan2
- SPATA3 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 16/314 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1352981577; called by muse, mutect2
- SSC4D | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 22/333 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.877); catalogued as rs1032117961; called by muse, mutect2
- STXBP5 | c.641G>T p.G214V | Missense Mutation (SNP) | VAF 53/233 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV51656151, COSV99470223; called by muse, mutect2, varscan2
- SYT13 | c.311C>G p.S104C | Missense Mutation (SNP) | VAF 201/562 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs780589479; called by muse, mutect2, varscan2
- TET3 | c.491G>T p.G164V | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV59880713; called by muse, mutect2
- TEX15 | c.3089del p.P1030Qfs*6 (on ENST00000256246; = p.P1413Qfs*6 on NM_001350162.2) | Frame Shift Del (DEL) | VAF 42/188 reads (22%) | catalogued as COSV56346972; called by mutect2, varscan2
- TEX15 | c.3088C>A p.P1030T (on ENST00000256246; = p.P1413T on NM_001350162.2) | Missense Mutation (SNP) | VAF 44/189 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs982208266; called by mutect2, varscan2
- TFR2 | c.455G>T p.R152L | Missense Mutation (SNP) | VAF 45/201 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.041); catalogued as rs578132648, COSV99031211; called by muse, mutect2, varscan2
- THRB | c.137G>C p.R46P | Missense Mutation (SNP) | VAF 178/307 reads (58%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as COSV100726166; called by muse, mutect2, varscan2
- TLR4 | c.1439G>C p.G480A (on ENST00000355622 / NM_138554.5; = p.G440A on NM_003266.4) | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV62923610; called by muse, mutect2, varscan2
- TMEM239 | c.556C>T p.H186Y (on ENST00000361033 / NM_001318207.1; = p.H143Y on NM_001167670.3) | Missense Mutation (SNP) | VAF 177/354 reads (50%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.342); catalogued as rs749692425; called by muse, mutect2, varscan2
- UBA52 | c.139G>T p.G47C | Missense Mutation (SNP) | VAF 38/177 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV55889071; called by mutect2, varscan2
- URI1 | c.422G>T p.R141I | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1385654392, COSV56349040; called by muse, mutect2, varscan2
- VWA5A | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 22/179 reads (12%) | catalogued as COSV63707407; called by muse, mutect2, varscan2
- XKR4 | c.1620C>A p.D540E | Missense Mutation (SNP) | VAF 83/250 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59302675; called by muse, mutect2, varscan2
- ZBED9 | c.465G>T p.M155I | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as COSV71729291; called by muse, mutect2, varscan2
- ZFHX4 | c.1126C>A p.P376T | Missense Mutation (SNP) | VAF 55/276 reads (20%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.1); catalogued as rs1248444058, COSV50607690; called by muse, mutect2, varscan2
- ZNF419 | c.493G>T p.G165W | Missense Mutation (SNP) | VAF 27/196 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs780020879; called by muse, mutect2, varscan2
- ZNF423 | c.2641G>T p.E881* (on ENST00000563137 / NM_001379286.1; = p.E873* on NM_015069.4) | Nonsense Mutation (SNP) | VAF 62/160 reads (39%) | catalogued as rs1555515010; called by muse, mutect2, varscan2
- ABCA13 | c.2346G>T p.K782N | Missense Mutation (SNP) | VAF 202/457 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- ABCA13 | c.3007A>G p.N1003D | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ABCA5 | c.2120G>T p.G707V | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ABCC2 | c.2762G>T p.G921V | Missense Mutation (SNP) | VAF 23/357 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- ABHD1 | c.1036C>A p.P346T | Missense Mutation (SNP) | VAF 56/345 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- ABLIM1 | c.852A>C p.K284N | Missense Mutation (SNP) | VAF 151/289 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- ADAM19 | c.1864G>T p.D622Y | Missense Mutation (SNP) | VAF 65/297 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADCY2 | c.1420del p.Q474Sfs*15 | Frame Shift Del (DEL) | VAF 35/107 reads (33%) | called by mutect2, pindel
- ADGRD2 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2
- ADRA1D | c.1595C>T p.A532V | Missense Mutation (SNP) | VAF 60/416 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- AFF2 | c.492T>A p.H164Q | Missense Mutation (SNP) | VAF 8/199 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2
- AHR | c.1993C>T p.P665S | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- ANKRD30B | c.2623G>T p.D875Y | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- ANKRD62 | c.390C>A p.N130K | Missense Mutation (SNP) | VAF 75/263 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ARAP2 | c.3839G>T p.S1280I | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); called by muse, mutect2
- ASPN | c.99T>A p.D33E | Missense Mutation (SNP) | VAF 84/249 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.444); called by muse, varscan2
- ATP1A3 | c.1386C>G p.C462W (on ENST00000545399 / NM_001256214.2; = p.C449W on NM_152296.5) | Missense Mutation (SNP) | VAF 293/607 reads (48%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- BCORL1 | c.2280G>C p.K760N | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.889); called by muse, mutect2
- BDKRB1 | c.406T>A p.Y136N | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CASQ2 | c.1012G>T p.D338Y | Missense Mutation (SNP) | VAF 79/272 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCDC102B | c.888G>T p.K296N | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CCDC148 | c.1376A>T p.K459I | Missense Mutation (SNP) | VAF 80/232 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- CCDC88B | c.2224G>T p.E742* | Nonsense Mutation (SNP) | VAF 19/325 reads (6%) | called by muse, mutect2
- CCDC91 | c.226G>T p.A76S | Missense Mutation (SNP) | VAF 60/249 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- CD1B | c.237G>T p.K79N | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.06); called by muse, mutect2
- CDH9 | c.404C>G p.T135S | Missense Mutation (SNP) | VAF 44/483 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.05); called by muse, mutect2
- CDR2 | c.293A>G p.N98S | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CIZ1 | c.92A>T p.Q31L | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CLEC5A | c.274T>G p.W92G | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CNGB3 | c.433C>A p.L145I | Missense Mutation (SNP) | VAF 332/663 reads (50%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, varscan2
- CNOT2 | c.1290+3G>T | Splice Region (SNP) | VAF 52/173 reads (30%) | called by muse, mutect2, varscan2
- COBLL1 | c.3390del p.P1131Qfs*12 (on ENST00000392717; = p.P1093Qfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 21/96 reads (22%) | called by mutect2, pindel, varscan2
- COL4A1 | c.355C>A p.P119T | Missense Mutation (SNP) | VAF 161/553 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL9A3 | c.1395dup p.G466Rfs*135 | Frame Shift Ins (INS) | VAF 185/534 reads (35%) | called by mutect2, pindel, varscan2
- CPXCR1 | c.850C>A p.L284I | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2
- CSMD3 | c.10078C>A p.H3360N (on ENST00000297405 / NM_001363185.1; = p.H3191N on NM_052900.3) | Missense Mutation (SNP) | VAF 177/845 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- CSMD3 | c.3311-2A>T p.X1104_splice (on ENST00000297405 / NM_001363185.1; = p.X1000_splice on NM_052900.3) | Splice Site (SNP) | VAF 62/255 reads (24%) | called by muse, mutect2, varscan2
- CSN3 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- DACH1 | c.1556C>A p.S519Y (on ENST00000619232 / NM_001366712.1; = p.S467Y on NM_080759.6) | Missense Mutation (SNP) | VAF 107/218 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- DCAF8L2 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.01); called by muse, varscan2
- DCAF8L2 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.141); called by muse, varscan2
- DENND1B | c.1060A>T p.T354S | Missense Mutation (SNP) | VAF 51/205 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- DLGAP3 | c.1598C>A p.S533Y | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- DNMT3L | c.38C>A p.P13H | Missense Mutation (SNP) | VAF 62/232 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- DYNC1H1 | c.12562G>A p.A4188T | Missense Mutation (SNP) | VAF 226/615 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DYTN | c.245A>C p.H82P | Missense Mutation (SNP) | VAF 70/303 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- EGF | c.3406C>A p.Q1136K | Missense Mutation (SNP) | VAF 16/191 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.024); called by muse, mutect2
- EML6 | c.5636A>C p.N1879T | Missense Mutation (SNP) | VAF 97/321 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- EPB42 | c.1145T>A p.V382E (on ENST00000441366 / NM_001114134.2; = p.V412E on NM_000119.3) | Missense Mutation (SNP) | VAF 82/352 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- EPHA5 | c.249G>T p.W83C | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- EPHB6 | c.2541C>A p.S847R | Missense Mutation (SNP) | VAF 28/607 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- EPPK1 | c.5632A>G p.T1878A | Missense Mutation (SNP) | VAF 52/241 reads (22%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- ERCC4 | c.1720G>T p.E574* | Nonsense Mutation (SNP) | VAF 20/77 reads (26%) | called by muse, mutect2, varscan2
- ERICH3 | c.4017dup p.V1340Cfs*9 | Frame Shift Ins (INS) | VAF 88/375 reads (23%) | called by mutect2, pindel, varscan2
- ERICH3 | c.3811C>A p.Q1271K | Missense Mutation (SNP) | VAF 115/507 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- FAM160A2 | c.382G>T p.A128S | Missense Mutation (SNP) | VAF 78/235 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- FAM178B | c.1308G>T p.Q436H | Missense Mutation (SNP) | VAF 121/287 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM180A | c.272C>A p.T91N | Missense Mutation (SNP) | VAF 83/187 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- FBLN1 | c.1109G>A p.G370E | Missense Mutation (SNP) | VAF 125/389 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FMN1 | c.3289-1G>T p.X1097_splice (on ENST00000616417 / NM_001277313.2; = p.X874_splice on NM_001103184.4) | Splice Site (SNP) | VAF 37/110 reads (34%) | called by muse, mutect2, varscan2
- FOXD4 | c.984G>T p.K328N | Missense Mutation (SNP) | VAF 204/837 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- FRMD4A | c.476T>A p.V159E | Missense Mutation (SNP) | VAF 34/220 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- FRMPD1 | c.1143G>T p.Q381H | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- FZD2 | c.1230C>G p.D410E | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- GAS7 | c.1399G>A p.G467S (on ENST00000432992 / NM_201433.2; = p.G327S on NM_003644.3) | Missense Mutation (SNP) | VAF 64/386 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GCN1 | c.2712G>T p.L904F | Missense Mutation (SNP) | VAF 43/452 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- GLDN | c.1542G>T p.Q514H | Missense Mutation (SNP) | VAF 34/202 reads (17%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.958); called by mutect2, varscan2
- GLE1 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 117/361 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- HBD | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 214/644 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- HEATR5A | c.4502G>A p.W1501* | Nonsense Mutation (SNP) | VAF 19/377 reads (5%) | called by muse, mutect2
- IGHG1 | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 120/332 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- IGLV5-45 | c.184G>C p.G62R | Missense Mutation (SNP) | VAF 68/357 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- IL21R | c.932C>A p.P311H | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- IRS1 | c.1288G>T p.E430* | Nonsense Mutation (SNP) | VAF 17/59 reads (29%) | called by muse, mutect2, varscan2
- ITGA11 | c.3167C>A p.P1056Q | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.458); called by muse, varscan2
- JAK2 | c.264G>T p.M88I | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- JPH3 | c.524C>A p.T175K | Missense Mutation (SNP) | VAF 51/200 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- KBTBD11 | c.1496A>T p.D499V | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- KCNC4 | c.872G>T p.W291L | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KCNH8 | c.2303G>T p.R768I | Missense Mutation (SNP) | VAF 155/288 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- KERA | c.845C>A p.A282D | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- KIAA1109 | c.1495A>G p.T499A | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KIAA1549L | c.737T>A p.L246H (on ENST00000321505; = p.L543H on NM_012194.3) | Missense Mutation (SNP) | VAF 41/188 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- KIF4B | c.478C>A p.Q160K | Missense Mutation (SNP) | VAF 127/386 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KLK3 | c.360C>A p.D120E | Missense Mutation (SNP) | VAF 45/295 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KLK7 | c.455C>A p.T152N | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- KRT25 | c.906G>T p.M302I | Missense Mutation (SNP) | VAF 68/388 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KRT76 | c.1760G>A p.G587D | Missense Mutation (SNP) | VAF 42/185 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- KRT80 | c.1223G>T p.R408M | Missense Mutation (SNP) | VAF 130/319 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- KRTAP2-3 | c.85T>A p.C29S | Missense Mutation (SNP) | VAF 89/325 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- LBX2 | c.253C>G p.R85G (on ENST00000377566 / NM_001282430.2; = p.R81G on NM_001009812.2) | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- LMBRD1 | c.994A>T p.I332L (on ENST00000649011; = p.I310L on NM_018368.4) | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- LRFN2 | c.1090G>C p.A364P | Missense Mutation (SNP) | VAF 61/297 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- LRRD1 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 55/125 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRK1 | c.2771C>A p.P924H | Missense Mutation (SNP) | VAF 69/279 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- MAGEA11 | c.214C>A p.L72M | Missense Mutation (SNP) | VAF 82/115 reads (71%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MCOLN2 | c.1057A>G p.S353G | Missense Mutation (SNP) | VAF 66/226 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- MEFV | c.996C>A p.C332* | Nonsense Mutation (SNP) | VAF 25/55 reads (45%) | called by muse, mutect2, varscan2
- MRGPRX1 | c.796A>T p.S266C | Missense Mutation (SNP) | VAF 115/472 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- MUC16 | c.42607C>A p.Q14203K | Missense Mutation (SNP) | VAF 88/162 reads (54%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- MYH2 | c.3391G>C p.E1131Q | Missense Mutation (SNP) | VAF 283/739 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- MYH2 | c.1802del p.K601Rfs*4 | Frame Shift Del (DEL) | VAF 80/471 reads (17%) | called by mutect2, pindel, varscan2
- MYH8 | c.1123C>A p.Q375K | Missense Mutation (SNP) | VAF 113/692 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MYOZ2 | c.539C>A p.P180H | Missense Mutation (SNP) | VAF 48/242 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NAV3 | c.6195G>T p.L2065F (on ENST00000397909 / NM_001024383.2; = p.L2043F on NM_014903.6) | Missense Mutation (SNP) | VAF 53/272 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- NBPF4 | c.66G>C p.Q22H | Missense Mutation (SNP) | VAF 44/274 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- NCOA2 | c.1075C>G p.Q359E | Missense Mutation (SNP) | VAF 11/272 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.099); called by muse, mutect2
- NEGR1 | c.831C>A p.S277R | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- NID2 | c.2278G>T p.G760W | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- NLRP9 | c.982G>T p.G328W | Missense Mutation (SNP) | VAF 33/216 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- NOTCH3 | c.2092C>T p.P698S | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.07); called by muse, varscan2
- NRXN1 | c.469G>T p.G157W | Missense Mutation (SNP) | VAF 56/308 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NTNG1 | c.1016G>T p.S339I | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NXF3 | c.134C>G p.S45C | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- OR11H1 | c.399del p.L134Cfs*7 | Frame Shift Del (DEL) | VAF 60/356 reads (17%) | called by mutect2, pindel, varscan2
- OR2B3 | c.776A>G p.Y259C | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR2V2 | c.307G>T p.G103C | Missense Mutation (SNP) | VAF 54/170 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR6C74 | c.82C>A p.L28I | Missense Mutation (SNP) | VAF 99/217 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- OTOG | c.1253T>A p.V418E | Missense Mutation (SNP) | VAF 69/214 reads (32%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- OTUD6A | c.154G>C p.E52Q | Missense Mutation (SNP) | VAF 187/245 reads (76%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- P2RX6 | c.1050+8C>G | Splice Region (SNP) | VAF 18/192 reads (9%) | called by muse, mutect2
- PAPPA2 | c.2513C>T p.T838I | Missense Mutation (SNP) | VAF 60/175 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- PBX4 | c.744G>T p.R248S | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- PCDH11X | c.196G>T p.V66L | Missense Mutation (SNP) | VAF 231/310 reads (75%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHGA12 | c.2392G>T p.V798L | Missense Mutation (SNP) | VAF 135/306 reads (44%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDXDC1 | c.896C>G p.P299R | Missense Mutation (SNP) | VAF 40/242 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PIGS | c.34G>T p.E12* | Nonsense Mutation (SNP) | VAF 35/145 reads (24%) | called by muse, mutect2, varscan2
- PKD1L3 | c.162G>T p.Q54H | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PLA2G12A | c.560C>T p.T187I | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- POLQ | c.2278G>C p.G760R | Missense Mutation (SNP) | VAF 104/157 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- POU1F1 | c.280C>A p.H94N | Missense Mutation (SNP) | VAF 59/112 reads (53%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- POU3F2 | c.874G>A p.G292R | Missense Mutation (SNP) | VAF 146/494 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POU6F2 | c.902T>A p.L301Q | Missense Mutation (SNP) | VAF 123/273 reads (45%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- PRRC2B | c.6220C>T p.P2074S | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- PTH2R | c.553del p.V185Cfs*5 | Frame Shift Del (DEL) | VAF 25/84 reads (30%) | called by mutect2, pindel, varscan2
- PTPN21 | c.2998G>A p.E1000K | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- RHOBTB1 | c.1025A>T p.Q342L | Missense Mutation (SNP) | VAF 18/353 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.045); called by muse, mutect2
- RIMS2 | c.1330G>T p.D444Y (on ENST00000666250 / NM_001348490.2; = p.D252Y on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 104/359 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RIMS2 | c.2145G>T p.M715I (on ENST00000666250 / NM_001348490.2; = p.M523I on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/294 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.675); called by muse, mutect2
- RIOK3 | c.1420A>G p.T474A | Missense Mutation (SNP) | VAF 71/194 reads (37%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- RPS6KA4 | c.1919G>T p.W640L | Missense Mutation (SNP) | VAF 59/144 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RTL1 | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 63/210 reads (30%) | called by muse, mutect2, varscan2
- RTTN | c.3151G>T p.D1051Y | Missense Mutation (SNP) | VAF 64/177 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- SALL3 | c.419G>A p.G140E | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCN7A | c.2473_2475del p.S825del | In Frame Del (DEL) | VAF 49/261 reads (19%) | called by mutect2, pindel, varscan2
- SCN8A | c.3119del p.K1040Rfs*53 | Frame Shift Del (DEL) | VAF 144/404 reads (36%) | called by mutect2, pindel, varscan2
- SERPING1 | c.89G>T p.S30I | Missense Mutation (SNP) | VAF 74/324 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- SETBP1 | c.2350G>T p.G784C | Missense Mutation (SNP) | VAF 378/920 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- SETD1B | c.1117C>T p.Q373* | Nonsense Mutation (SNP) | VAF 65/128 reads (51%) | called by muse, mutect2, varscan2
- SH2D4A | c.-205G>C | Splice Region (SNP) | VAF 14/134 reads (10%) | called by muse, mutect2
- SIRT1 | c.1009G>T p.G337* | Nonsense Mutation (SNP) | VAF 14/251 reads (6%) | called by muse, mutect2
- SLC12A6 | c.3388G>T p.E1130* (on ENST00000354181 / NM_001365088.1; = p.E1079* on NM_005135.2) | Nonsense Mutation (SNP) | VAF 19/284 reads (7%) | called by muse, mutect2
- SLC25A14 | c.573A>T p.E191D | Missense Mutation (SNP) | VAF 124/155 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC25A42 | c.395G>T p.W132L | Missense Mutation (SNP) | VAF 82/166 reads (49%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLCO5A1 | c.1804A>T p.T602S | Missense Mutation (SNP) | VAF 56/200 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SNTB1 | c.1303T>G p.S435A | Missense Mutation (SNP) | VAF 116/463 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SOX5 | c.808C>A p.Q270K | Missense Mutation (SNP) | VAF 34/333 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SPRR2E | c.95G>C p.C32S | Missense Mutation (SNP) | VAF 206/731 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.856); called by muse, varscan2
- SSC4D | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 20/332 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); called by muse, mutect2
- ST8SIA3 | c.1026dup p.G343Rfs*17 | Frame Shift Ins (INS) | VAF 86/290 reads (30%) | called by mutect2, pindel, varscan2
- SVEP1 | c.6818G>A p.G2273D | Missense Mutation (SNP) | VAF 40/175 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SWAP70 | c.1463A>T p.Q488L | Missense Mutation (SNP) | VAF 33/646 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2
- SYNE2 | c.3044T>G p.V1015G | Missense Mutation (SNP) | VAF 23/666 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2
- TAF7L | c.977G>A p.S326N | Missense Mutation (SNP) | VAF 113/150 reads (75%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TBX4 | c.1333C>A p.H445N | Missense Mutation (SNP) | VAF 126/282 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- TDGF1 | c.246C>A p.C82* | Nonsense Mutation (SNP) | VAF 104/209 reads (50%) | called by muse, mutect2, varscan2
- TEAD3 | c.203G>T p.G68V | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TGM3 | c.8-1G>A p.X3_splice | Splice Site (SNP) | VAF 9/152 reads (6%) | called by muse, mutect2
- TIMELESS | c.2643-2A>T p.X881_splice | Splice Site (SNP) | VAF 125/300 reads (42%) | called by muse, mutect2, varscan2
- TMC3 | c.1183C>A p.Q395K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- TMEM131 | c.4889G>T p.S1630I | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- TMEM135 | c.1060G>T p.A354S | Missense Mutation (SNP) | VAF 46/319 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- TMEM215 | c.61del p.L21Sfs*12 | Frame Shift Del (DEL) | VAF 56/171 reads (33%) | called by mutect2, pindel, varscan2
- TNR | c.2973A>T p.A991= | Splice Region (SNP) | VAF 118/293 reads (40%) | called by muse, mutect2, varscan2
- TNRC18 | c.2405A>T p.H802L | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2
- TRIM43B | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 36/478 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TRIM49B | c.514G>T p.V172L | Missense Mutation (SNP) | VAF 141/372 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- TRMT12 | c.882C>A p.N294K | Missense Mutation (SNP) | VAF 66/517 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TRPA1 | c.1643G>T p.G548V | Missense Mutation (SNP) | VAF 118/517 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRPM3 | c.2507T>C p.M836T (on ENST00000357533 / NM_001366142.2; = p.M679T on NM_020952.6) | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.014); called by muse, mutect2
- TTC37 | c.3523A>C p.S1175R | Missense Mutation (SNP) | VAF 175/383 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- TUBA8 | c.1169dup p.L391Pfs*30 | Frame Shift Ins (INS) | VAF 63/174 reads (36%) | called by mutect2, pindel, varscan2
- UFD1 | c.267G>T p.E89D | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- UGT3A2 | c.1106A>C p.H369P | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- UROC1 | c.1760T>A p.V587D | Missense Mutation (SNP) | VAF 273/428 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- USP10 | c.133G>T p.V45L | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- USP8 | c.679A>T p.S227C | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); called by muse, mutect2
- VEZF1 | c.1408G>T p.V470F | Missense Mutation (SNP) | VAF 269/510 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- VGLL1 | c.526A>T p.R176* | Nonsense Mutation (SNP) | VAF 144/185 reads (78%) | called by muse, mutect2, varscan2
- VNN2 | c.944C>A p.P315Q | Missense Mutation (SNP) | VAF 51/244 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- VWA8 | c.2981G>T p.G994V | Missense Mutation (SNP) | VAF 76/149 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2
- VWF | c.1169T>A p.V390D | Missense Mutation (SNP) | VAF 228/479 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- WNK2 | c.4723C>T p.P1575S (on ENST00000297954 / NM_001282394.1; = p.P1538S on NM_006648.3) | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- WNT8A | c.489C>A p.H163Q | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- XIRP2 | c.6736C>A p.P2246T (on ENST00000628543; = p.P2421T on NM_152381.6) | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- XRCC4 | c.389G>A p.C130Y | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, varscan2
- ZAN | c.5996A>T p.Q1999L | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZKSCAN1 | c.1622G>T p.R541I | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF300 | c.1321C>T p.Q441* | Nonsense Mutation (SNP) | VAF 55/170 reads (32%) | called by muse, mutect2, varscan2
- ZNF334 | c.1637G>A p.C546Y | Missense Mutation (SNP) | VAF 71/150 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF468 | c.1304G>T p.G435V | Missense Mutation (SNP) | VAF 37/348 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ZNF532 | c.530A>T p.K177M | Missense Mutation (SNP) | VAF 91/265 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- ZNF615 | c.106G>T p.V36L | Missense Mutation (SNP) | VAF 87/454 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- ZNF710 | c.1351_1352insTTCT p.Q451Lfs*18 | Frame Shift Ins (INS) | VAF 28/138 reads (20%) | called by mutect2, pindel*, varscan2
- ZNF804B | c.2755G>T p.E919* | Nonsense Mutation (SNP) | VAF 29/239 reads (12%) | called by muse, mutect2, varscan2
- ZNF93 | c.17T>A p.F6Y | Missense Mutation (SNP) | VAF 126/619 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF98 | c.643T>C p.C215R | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- A4GNT | c.807G>A p.R269= | Silent (SNP) | VAF 201/294 reads (68%) | called by muse, mutect2, varscan2
- ABCC6 | c.3408G>T p.V1136= | Silent (SNP) | VAF 58/195 reads (30%) | called by muse, mutect2, varscan2
- ADAMTS20 | c.2643T>A p.V881= | Silent (SNP) | VAF 30/150 reads (20%) | called by muse, mutect2, varscan2
- AGA | c.927G>A p.V309= | Silent (SNP) | VAF 24/458 reads (5%) | catalogued as rs1246565561; called by muse, mutect2
- AL121899.2 | c.930C>A p.S310= | Silent (SNP) | VAF 153/322 reads (48%) | called by muse, mutect2, varscan2
- ANKRD30B | c.3462G>A p.E1154= | Silent (SNP) | VAF 20/182 reads (11%) | called by muse, mutect2
- ASPM | c.5526A>G p.V1842= | Silent (SNP) | VAF 124/292 reads (42%) | called by muse, mutect2, varscan2
- BPI | c.597C>T p.N199= (on ENST00000262865; = p.N195= on NM_001725.3) | Silent (SNP) | VAF 42/214 reads (20%) | called by muse, mutect2, varscan2
- CCDC141 | c.2604A>G p.L868= | Silent (SNP) | VAF 29/78 reads (37%) | called by muse, mutect2, varscan2
- CD6 | c.1863C>A p.S621= | Silent (SNP) | VAF 23/115 reads (20%) | called by muse, mutect2, varscan2
- CDC20B | c.45G>T p.T15= | Silent (SNP) | VAF 61/263 reads (23%) | called by muse, mutect2, varscan2
- CHRND | c.627G>A p.G209= | Silent (SNP) | VAF 17/74 reads (23%) | called by muse, mutect2, varscan2
- CHST8 | c.1113C>A p.P371= | Silent (SNP) | VAF 118/236 reads (50%) | called by muse, mutect2, varscan2
- CPS1 | c.1353C>A p.A451= | Silent (SNP) | VAF 74/252 reads (29%) | called by muse, mutect2, varscan2
- CYP2C9 | c.522C>A p.P174= | Silent (SNP) | VAF 72/299 reads (24%) | called by muse, mutect2, varscan2
- DHX57 | c.2172A>G p.T724= | Silent (SNP) | VAF 36/165 reads (22%) | called by muse, mutect2, varscan2
- DIO3 | c.465G>A p.A155= | Silent (SNP) | VAF 28/334 reads (8%) | catalogued as rs540396975, COSV100832047; called by muse, mutect2
- DNAH7 | c.3420G>A p.V1140= | Silent (SNP) | VAF 41/162 reads (25%) | catalogued as rs1214291005; called by muse, mutect2, varscan2
- ERCC4 | c.1719G>T p.V573= | Silent (SNP) | VAF 19/76 reads (25%) | called by muse, mutect2, varscan2
- ERICH3 | c.3810C>A p.T1270= | Silent (SNP) | VAF 117/507 reads (23%) | catalogued as COSV100445144; called by muse, mutect2, varscan2
- FAM210B | c.129G>A p.P43= | Silent (SNP) | VAF 24/63 reads (38%) | called by muse, mutect2
- FRAS1 | c.180T>C p.P60= | Silent (SNP) | VAF 17/87 reads (20%) | called by muse, varscan2
- GAL3ST2 | c.255C>G p.P85= | Silent (SNP) | VAF 32/334 reads (10%) | called by muse, mutect2
- GLI3 | c.2829G>T p.T943= | Silent (SNP) | VAF 202/466 reads (43%) | called by mutect2, varscan2
- GOLGA8S | c.546G>T p.R182= | Silent (SNP) | VAF 34/516 reads (7%) | catalogued as rs1410398859; called by muse, mutect2
- GPR142 | c.876C>A p.P292= | Silent (SNP) | VAF 76/330 reads (23%) | called by muse, mutect2, varscan2
- GRIK1 | c.2097G>A p.A699= | Silent (SNP) | VAF 63/130 reads (48%) | catalogued as rs568601127; ClinVar: likely benign; called by muse, mutect2, varscan2
- IKZF2 | c.1431A>C p.R477= | Silent (SNP) | VAF 20/256 reads (8%) | catalogued as rs144578334; called by muse, mutect2
- INSYN2B | c.1095A>T p.S365= | Silent (SNP) | VAF 18/98 reads (18%) | called by muse, mutect2, varscan2
- KCNA5 | c.1206C>A p.I402= | Silent (SNP) | VAF 28/253 reads (11%) | catalogued as rs1400673691, COSV99364158; called by muse, mutect2, varscan2
- KCNH1 | c.1902G>T p.V634= (on ENST00000271751 / NM_172362.3; = p.V607= on NM_002238.4) | Silent (SNP) | VAF 64/144 reads (44%) | called by muse, mutect2, varscan2
- KLHL22 | c.117G>T p.G39= | Silent (SNP) | VAF 133/473 reads (28%) | called by muse, mutect2, varscan2
- KLK7 | c.456C>T p.T152= | Silent (SNP) | VAF 21/139 reads (15%) | called by muse, mutect2, varscan2
- LILRB2 | c.1338C>A p.P446= | Silent (SNP) | VAF 27/61 reads (44%) | catalogued as rs781388755; called by muse, mutect2, varscan2
- MAG | c.843G>T p.R281= | Silent (SNP) | VAF 17/103 reads (17%) | called by muse, mutect2, varscan2
- MED12L | c.3939T>C p.R1313= | Silent (SNP) | VAF 31/61 reads (51%) | called by muse, mutect2, varscan2
- MORC1 | c.1443A>G p.P481= | Silent (SNP) | VAF 80/157 reads (51%) | catalogued as rs148118053; called by muse, mutect2, varscan2
- MTUS2 | c.414G>T p.V138= | Silent (SNP) | VAF 112/317 reads (35%) | catalogued as COSV70912437; called by muse, mutect2, varscan2
- NOTCH3 | c.2037C>T p.F679= | Silent (SNP) | VAF 63/322 reads (20%) | catalogued as COSV54629336; called by muse, varscan2
- NPAP1 | c.213G>T p.P71= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV100276413; called by muse, mutect2, varscan2
- NPEPL1 | c.468G>T p.V156= | Silent (SNP) | VAF 42/162 reads (26%) | catalogued as COSV100622348; called by muse, mutect2, varscan2
- OCIAD1 | c.213C>G p.P71= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as rs374128336; called by muse, mutect2, varscan2
- OR11A1 | c.696G>T p.G232= | Silent (SNP) | VAF 49/108 reads (45%) | called by muse, mutect2, varscan2
- OR2AJ1 | c.820C>T p.L274= | Silent (SNP) | VAF 80/203 reads (39%) | called by muse, mutect2, varscan2
- OR2M5 | c.237C>A p.P79= | Silent (SNP) | VAF 66/302 reads (22%) | catalogued as COSV100822819, COSV100822863; called by muse, mutect2, varscan2
- OR2M7 | c.315A>T p.I105= | Silent (SNP) | VAF 134/334 reads (40%) | called by muse, mutect2
- OR2V2 | c.309C>G p.G103= | Silent (SNP) | VAF 52/166 reads (31%) | called by muse, mutect2
- OR8A1 | c.174C>A p.P58= | Silent (SNP) | VAF 134/264 reads (51%) | catalogued as COSV52510714; called by muse, mutect2, varscan2
- OTOG | c.2856G>T p.G952= | Silent (SNP) | VAF 12/34 reads (35%) | called by muse, mutect2, varscan2
- PCDH15 | c.2811G>T p.P937= | Silent (SNP) | VAF 12/348 reads (3%) | catalogued as COSV57267597; called by muse, mutect2
- PCDHA11 | c.1722C>A p.G574= | Silent (SNP) | VAF 80/410 reads (20%) | called by muse, mutect2, varscan2
- PCDHB14 | c.1056T>A p.I352= | Silent (SNP) | VAF 30/110 reads (27%) | called by muse, mutect2, varscan2
- PCDHB5 | c.1221A>G p.T407= | Silent (SNP) | VAF 32/584 reads (5%) | called by muse, mutect2
- PIK3CG | c.1203C>A p.P401= | Silent (SNP) | VAF 189/497 reads (38%) | catalogued as COSV63247777; called by muse, mutect2, varscan2
- PKHD1 | c.312G>T p.L104= | Silent (SNP) | VAF 65/346 reads (19%) | catalogued as COSV100584218; called by muse, mutect2, varscan2
- POU6F2 | c.399C>A p.G133= | Silent (SNP) | VAF 222/532 reads (42%) | called by muse, varscan2
- RPL10A | c.531T>C p.D177= | Silent (SNP) | VAF 25/191 reads (13%) | catalogued as rs554872305; called by muse, mutect2, varscan2
- RUNX1T1 | c.1779G>T p.P593= (on ENST00000265814 / NM_001198628.1; = p.P566= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 142/482 reads (29%) | catalogued as COSV104380121; called by muse, varscan2
- SH3TC2 | c.1131G>C p.R377= | Silent (SNP) | VAF 115/547 reads (21%) | called by muse, mutect2, varscan2
- SLC18A1 | c.594C>A p.T198= | Silent (SNP) | VAF 56/473 reads (12%) | called by muse, mutect2, varscan2
- SYN2 | c.543C>T p.D181= | Silent (SNP) | VAF 12/85 reads (14%) | called by muse, mutect2
- TAF4 | c.699C>A p.A233= | Silent (SNP) | VAF 10/114 reads (9%) | called by muse, mutect2
- TEKT4 | c.873C>T p.A291= | Silent (SNP) | VAF 28/294 reads (10%) | catalogued as rs571650482; called by muse, mutect2, varscan2
- TGM6 | c.1827C>A p.T609= | Silent (SNP) | VAF 48/694 reads (7%) | catalogued as COSV52479226; called by muse, mutect2
- THBS2 | c.507C>A p.L169= | Silent (SNP) | VAF 41/150 reads (27%) | catalogued as COSV64681367; called by muse, mutect2, varscan2
- TMEM128 | c.126G>A p.E42= (on ENST00000382753 / NM_001297552.2; = p.E18= on NM_032927.3) | Silent (SNP) | VAF 55/132 reads (42%) | catalogued as COSV54637610; called by muse, mutect2, varscan2
- TMEM272 | c.99G>T p.P33= | Silent (SNP) | VAF 90/244 reads (37%) | catalogued as rs1391072383; called by muse, mutect2, varscan2
- TNC | c.1005C>T p.G335= | Silent (SNP) | VAF 76/283 reads (27%) | called by muse, mutect2, varscan2
- TRPA1 | c.2847A>T p.P949= | Silent (SNP) | VAF 14/265 reads (5%) | called by muse, mutect2
- TRPV6 | c.906G>A p.K302= | Silent (SNP) | VAF 13/54 reads (24%) | called by muse, mutect2, varscan2
- TSGA10 | c.525G>T p.V175= | Silent (SNP) | VAF 60/226 reads (27%) | called by muse, mutect2, varscan2
- UNC80 | c.4509T>C p.Y1503= | Silent (SNP) | VAF 112/381 reads (29%) | called by muse, varscan2
- VCAM1 | c.1227C>A p.I409= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as rs749566790; called by muse, mutect2, varscan2
- VCAN | c.2256G>A p.L752= | Silent (SNP) | VAF 104/435 reads (24%) | called by muse, mutect2, varscan2
- VCX3A | c.330G>T p.L110= | Silent (SNP) | VAF 228/966 reads (24%) | called by muse, varscan2
- VGF | c.243G>A p.A81= | Silent (SNP) | VAF 24/88 reads (27%) | called by muse, mutect2, varscan2
- VPS35L | c.1164C>T p.L388= | Silent (SNP) | VAF 51/209 reads (24%) | called by muse, mutect2, varscan2
- VRK2 | c.744T>G p.L248= | Silent (SNP) | VAF 101/264 reads (38%) | called by muse, mutect2, varscan2
- XIRP1 | c.1953C>G p.V651= | Silent (SNP) | VAF 124/208 reads (60%) | called by muse, mutect2, varscan2
- ZFHX4 | c.10293T>C p.P3431= | Silent (SNP) | VAF 136/268 reads (51%) | called by muse, mutect2, varscan2
- ZNF559 | c.1386G>A p.E462= | Silent (SNP) | VAF 90/182 reads (49%) | catalogued as COSV57834976; called by muse, mutect2, varscan2
- ZNFX1 | c.2073G>A p.Q691= | Silent (SNP) | VAF 90/243 reads (37%) | called by muse, mutect2, varscan2
- AC090155.1 | n.195T>A | RNA (SNP) | VAF 112/514 reads (22%) | called by muse, mutect2, varscan2
- AC133561.1 | n.1400G>T | RNA (SNP) | VAF 50/320 reads (16%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73848727 A>T | 5'Flank (SNP) | VAF 38/205 reads (19%) | called by muse, mutect2, varscan2
- AL627230.3 | c.76-129G>C | Intron (SNP) | VAF 66/625 reads (11%) | called by muse, mutect2
- ARMC5 | chr16:31459340 G>T | 5'Flank (SNP) | VAF 42/220 reads (19%) | called by muse, mutect2, varscan2
- CACNA1B | c.530+9489G>T | Intron (SNP) | VAF 46/122 reads (38%) | called by muse, mutect2, varscan2
- CCHCR1 | c.1798+38G>T | Intron (SNP) | VAF 19/74 reads (26%) | called by muse, mutect2, varscan2
- CHMP1A | c.106-15C>T | Intron (SNP) | VAF 71/195 reads (36%) | catalogued as rs970303465; called by muse, mutect2, varscan2
- COL17A1 | c.838+36T>A | Intron (SNP) | VAF 228/426 reads (54%) | called by muse, mutect2, varscan2
- DDX39B | c.736-44C>T | Intron (SNP) | VAF 5/20 reads (25%) | catalogued as rs778246801; called by muse, varscan2
- DENND10P1 | n.263T>C | RNA (SNP) | VAF 32/400 reads (8%) | called by muse, mutect2
- DNM1L | chr12:32679235 C>G | 5'Flank (SNP) | VAF 31/108 reads (29%) | called by muse, mutect2, varscan2
- DST | c.414+7113G>C | Intron (SNP) | VAF 83/220 reads (38%) | called by muse, mutect2, varscan2
- ERVV-1 | chr19:53009613 G>A | 5'Flank (SNP) | VAF 66/376 reads (18%) | catalogued as rs1256062006; called by muse, mutect2, varscan2
- GON4L | c.1788+138G>A | Intron (SNP) | VAF 115/345 reads (33%) | called by muse, mutect2, varscan2
- ING5 | c.*23G>T | 3'UTR (SNP) | VAF 88/255 reads (35%) | catalogued as COSV100545860, COSV100545890; called by muse, mutect2, varscan2
- IQCA1 | c.1956+806G>C | Intron (SNP) | VAF 75/245 reads (31%) | called by muse, mutect2, varscan2
- ITK | c.1233-19C>T | Intron (SNP) | VAF 113/322 reads (35%) | called by muse, mutect2, varscan2
- JAKMIP1 | chr4:6050644 T>A | 3'Flank (SNP) | VAF 53/229 reads (23%) | called by muse, mutect2, varscan2
- KLF6 | c.*1037G>A | 3'UTR (SNP) | VAF 18/302 reads (6%) | called by muse, mutect2
- LAMB2 | c.4573+28G>A | Intron (SNP) | VAF 191/328 reads (58%) | called by muse, mutect2, varscan2
- LINC01605 | n.493A>T | RNA (SNP) | VAF 188/374 reads (50%) | called by muse, mutect2, varscan2
- LINC02312 | n.655G>T | RNA (SNP) | VAF 66/206 reads (32%) | called by muse, mutect2, varscan2
- LRP1B | c.13247+953C>A | Intron (SNP) | VAF 28/147 reads (19%) | catalogued as COSV67286103; called by muse, mutect2, varscan2
- MAPK15 | c.-6G>T | 5'UTR (SNP) | VAF 11/246 reads (4%) | called by muse, mutect2
- MIR100 | n.37A>G | RNA (SNP) | VAF 8/148 reads (5%) | called by muse, mutect2
- MIR9-1HG | n.402T>A | RNA (SNP) | VAF 133/410 reads (32%) | called by muse, mutect2, varscan2
- MORF4 | n.687G>T | RNA (SNP) | VAF 61/196 reads (31%) | called by muse, mutect2, varscan2
- MORF4 | n.686G>T | RNA (SNP) | VAF 60/198 reads (30%) | called by muse, mutect2, varscan2
- MSL3P1 | n.1181T>A | RNA (SNP) | VAF 62/258 reads (24%) | called by muse, mutect2, varscan2
- MYH16 | n.4304C>A | RNA (SNP) | VAF 47/249 reads (19%) | called by muse, mutect2, varscan2
- NF1 | c.7869+21A>T | Intron (SNP) | VAF 80/343 reads (23%) | called by muse, mutect2, varscan2
- NKIRAS2 | c.336+499C>T | Intron (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2, varscan2
- NMU | c.-45G>C | 5'UTR (SNP) | VAF 11/29 reads (38%) | called by muse, varscan2
- NOL4L-DT | n.554C>A | RNA (SNP) | VAF 23/136 reads (17%) | called by muse, mutect2, varscan2
- NRG1 | chr8:31640125 G>T | 5'Flank (SNP) | VAF 26/62 reads (42%) | called by muse, mutect2, varscan2
- PDE2A | c.324-934C>A | Intron (SNP) | VAF 82/415 reads (20%) | called by muse, mutect2, varscan2
- PHF21A | c.1785+400G>T | Intron (SNP) | VAF 121/294 reads (41%) | catalogued as rs1286806178; called by muse, mutect2, varscan2
- PIPSL | n.2117T>A | RNA (SNP) | VAF 28/520 reads (5%) | called by muse, mutect2
- PRMT7 | chr16:68311071 G>A | 5'Flank (SNP) | VAF 11/60 reads (18%) | called by muse, mutect2, varscan2
- RBBP4 | c.-44C>T | 5'UTR (SNP) | VAF 32/84 reads (38%) | called by muse, mutect2, varscan2
- RYR1 | c.3381+22A>G | Intron (SNP) | VAF 10/116 reads (9%) | called by muse, mutect2
- SGCD | c.696+30del | Intron (DEL) | VAF 21/73 reads (29%) | called by mutect2, pindel, varscan2
- SIGLEC17P | n.100G>T | RNA (SNP) | VAF 72/155 reads (46%) | called by muse, mutect2, varscan2
- TEX35 | c.341+113G>T | Intron (SNP) | VAF 50/305 reads (16%) | catalogued as rs1415941240; called by muse, mutect2, varscan2
- TEX51 | chr2:126901968 C>A | 3'Flank (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2, varscan2
- TMEM70 | c.*936G>T | 3'UTR (SNP) | VAF 105/359 reads (29%) | called by muse, mutect2, varscan2
- TNFRSF11A | c.*18G>T | 3'UTR (SNP) | VAF 24/97 reads (25%) | catalogued as rs760840919; called by muse, mutect2, varscan2
- TUBBP5 | n.1289G>T | RNA (SNP) | VAF 90/450 reads (20%) | called by muse, mutect2, varscan2
- UBR7 | c.*121G>T | 3'UTR (SNP) | VAF 73/213 reads (34%) | called by muse, mutect2, varscan2
- WDPCP | c.1748+8942G>T | Intron (SNP) | VAF 73/336 reads (22%) | catalogued as rs935216641; called by muse, mutect2, varscan2
- ZEB2 | chr2:144520040 C>A | 5'Flank (SNP) | VAF 20/356 reads (6%) | called by muse, mutect2
- ZNF783 | c.*973-63G>T | Intron (SNP) | VAF 34/79 reads (43%) | called by muse, mutect2, varscan2
